Somatic mutation profile of tumor specimen TCGA-FF-A7CR-01A (aliquot TCGA-FF-A7CR-01A-11D-A382-10) from TCGA case TCGA-FF-A7CR, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 61.5 years (22,471 days).
Specimen TCGA-FF-A7CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cdecb03-1306-4ccb-8be9-41a0860c8e6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-A7CR-10A (Blood Derived Normal), aliquot TCGA-FF-A7CR-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a94e0927-0238-45d7-ab63-cbabdea123bc

The open-access MAF lists 201 somatic variants for this specimen: 144 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 52, Nonsense Mutation 7, RNA 4, Frame Shift Del 3, Splice Site 3, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008878.1 | c.98A>T p.K33I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | PolyPhen possibly damaging (0.85); catalogued as COSV99900301; called by muse, mutect2, varscan2
- AC100868.1 | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99224988; called by muse, mutect2, varscan2
- AC242842.3 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 3/56 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1185110962; called by muse, mutect2
- ACTG1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100111767; called by muse, varscan2
- ADCK1 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as rs142956948, COSV99450632; called by muse, mutect2, varscan2
- AHCYL1 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1478067496, COSV100779302; called by muse, mutect2, varscan2
- AIDA | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.305); catalogued as COSV100387985; called by muse, mutect2, varscan2
- AMOTL2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs554025750, COSV51440529; called by muse, mutect2, varscan2
- ANGPTL7 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs376924013; called by muse, mutect2, varscan2
- ARC | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV100751643; called by muse, mutect2, varscan2
- ARHGAP21 | c.695C>G p.T232S | Missense Mutation (SNP) | VAF 83/336 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV100255606; called by muse, mutect2, varscan2
- ATG4C | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100507749; called by muse, mutect2, varscan2
- BCL11A | c.812C>T p.P271L (on ENST00000335712 / NM_001365609.1; = p.P305L on NM_018014.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100184562; called by muse, mutect2, varscan2
- BEND5 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1395610711, COSV100884074; called by muse, mutect2
- BTG1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV99755291, COSV99755427; called by muse, mutect2, varscan2
- BTG1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV99755294; called by muse, mutect2, varscan2
- C1QBP | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99852117; called by muse, mutect2, varscan2
- CACNA1E | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62396394; called by muse, mutect2, varscan2
- CASR | c.2455C>T p.R819C (on ENST00000490131; = p.R896C on NM_000388.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs749125441, COSV56140871; called by muse, mutect2, varscan2
- CCDC171 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs570101221, COSV99899632; called by muse, mutect2, varscan2
- CCDC185 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1428730032, COSV100838734; called by muse, mutect2, varscan2
- CD79B | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50075971, COSV50076112, COSV50076307; called by muse, mutect2, varscan2
- CDC42BPG | c.4609C>T p.R1537W | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs138706676; called by muse, mutect2, varscan2
- CDH26 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99721554; called by muse, mutect2, varscan2
- CDH7 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100541191, COSV59883801; called by muse, mutect2, varscan2
- CNTRL | c.5011A>G p.T1671A | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99440750; called by muse, mutect2, varscan2
- COL3A1 | c.2336A>C p.K779T | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100482206, COSV99049425; called by muse, mutect2, varscan2
- CXCR4 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs770327175, COSV99602408; called by muse, mutect2, varscan2
- CYP3A43 | c.752dup p.N251Kfs*4 | Frame Shift Ins (INS) | VAF 27/123 reads (22%) | catalogued as COSV99733205; called by mutect2, pindel, varscan2
- DGAT2L6 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs777214999, COSV60717997; called by muse, mutect2, varscan2
- DLC1 | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV99360338; called by muse, mutect2, varscan2
- DNAH5 | c.5153T>C p.F1718S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1220719773, COSV99443493; called by muse, mutect2, varscan2
- DSG3 | c.2095A>G p.S699G | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99933606; called by muse, mutect2, varscan2
- DUOX1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367526; called by muse, mutect2, varscan2
- EPHA3 | c.2667G>T p.K889N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100341795, COSV60713346, COSV60728845; called by muse, mutect2, varscan2
- ERG | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.44); catalogued as rs140222241; called by muse, mutect2, varscan2
- FAF1 | c.688A>T p.I230F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100875151; called by muse, mutect2, varscan2
- FOXC1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1050413147, COSV101083196; called by muse, varscan2
- GPR149 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101078016; called by muse, mutect2, varscan2
- GRHPR | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as CM154473, COSV100546771; called by muse, varscan2
- GRHPR | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.067); catalogued as COSV58943474; called by muse, varscan2
- GRID2 | c.1606T>G p.F536V | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99935929; called by muse, mutect2, varscan2
- GRM2 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99622303; called by muse, mutect2, varscan2
- H1-2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as rs79562358; called by muse, mutect2, varscan2
- H2AC20 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100479630; called by muse, mutect2, varscan2
- H4C12 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV100694730; called by muse, mutect2, varscan2
- HEPH | c.3196A>G p.T1066A (on ENST00000343002; = p.T799A on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100293887, COSV100294838; called by muse, mutect2, varscan2
- HIPK3 | c.3413C>T p.A1138V | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100305250; called by muse, mutect2, varscan2
- IGHD6-13 | c.2G>A p.G1E | Missense Mutation (SNP) | VAF 66/160 reads (41%) | catalogued as rs782195453; called by muse, varscan2
- IGHG2 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.072); catalogued as rs774006563; called by muse, mutect2, varscan2
- IGHM | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (1); catalogued as rs782080241; called by muse, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 117/520 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- IGLL5 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.119); catalogued as rs201857114, COSV66537362; called by muse, mutect2, varscan2
- IKZF3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as rs1455331938, COSV53103931, COSV99499063; called by muse, mutect2, varscan2
- IRF4 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66704400; called by muse, mutect2, varscan2
- ISLR | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99997074; called by muse, mutect2, varscan2
- ITPR1 | c.2998C>T p.R1000* (on ENST00000354582; = p.R985* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as rs1436270318, COSV56988176; called by muse, mutect2, varscan2
- KLF4 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV65929767; called by muse, mutect2, varscan2
- KLHL18 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV99230367; called by muse, mutect2, varscan2
- KLHL6 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548549593, COSV58068532, COSV58069328; called by muse, mutect2, varscan2
- KMT2D | c.6040C>T p.Q2014* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99976550; called by muse, mutect2, varscan2
- LIMS1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 93/912 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs375431434; called by muse, mutect2
- LRCH1 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100243220; called by muse, mutect2, varscan2
- LRRN3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57824362; called by muse, mutect2, varscan2
- MAGEB6 | c.495A>T p.K165N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.316); catalogued as COSV100983634; called by muse, mutect2, varscan2
- MAPKAPK2 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99685671; called by muse, mutect2, varscan2
- MAST1 | c.2912A>T p.Q971L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99262042; called by muse, mutect2, varscan2
- MCHR1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs200627010, COSV50761521; called by muse, mutect2, varscan2
- MESD | c.496T>G p.Y166D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as COSV99930708; called by muse, mutect2, varscan2
- MPEG1 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV99914865; called by muse, mutect2, varscan2
- MSANTD3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58492566; called by muse, mutect2, varscan2
- MTSS1 | c.2183_2185del p.G728del | In Frame Del (DEL) | VAF 52/206 reads (25%) | catalogued as rs1425480847; called by mutect2, pindel, varscan2
- MUC6 | c.5225C>A p.T1742K | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs372353242, COSV101424324; called by muse, mutect2
- MYD88 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57174632; called by muse, mutect2, varscan2
- MYH8 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV101238063; called by muse, mutect2, varscan2
- MYOM2 | c.3098G>T p.R1033L | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036355, COSV50740642; called by muse, mutect2, varscan2
- NAA11 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1235233451, COSV54516465; called by muse, mutect2, varscan2
- NAV3 | c.5252G>T p.G1751V | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as rs555983392, COSV99885885; called by muse, mutect2, varscan2
- NDST1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99938575; called by muse, mutect2, varscan2
- NEGR1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV100160087; called by muse, mutect2, varscan2
- NETO1 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100198025; called by muse, mutect2
- NOX4 | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99629212, COSV99629676; called by muse, mutect2, varscan2
- NPY4R | c.88T>G p.F30V | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as COSV100966090; called by muse, mutect2, varscan2
- NYAP2 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99795427; called by muse, mutect2, varscan2
- OR5D16 | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV101003795; called by muse, varscan2
- OR8B2 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV100899275; called by muse, mutect2, varscan2
- OR8G5 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1380668530, COSV100422162; called by muse, mutect2, varscan2
- OR8J1 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100274807; called by muse, mutect2, varscan2
- OSBPL10 | c.192C>G p.S64R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV100824358, COSV64383593; called by muse, varscan2
- OSBPL10 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100824360, COSV100824423; called by muse, varscan2
- OSBPL10 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as COSV100824361; called by muse, varscan2
- PCSK2 | c.178-1G>T p.X60_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99358410; called by muse, mutect2, varscan2
- PIM1 | c.159C>G p.Y53* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | catalogued as COSV100998570, COSV65165036; called by muse, mutect2, varscan2
- PIM1 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100998571, COSV104423821, COSV65164906; called by muse, varscan2
- PIM1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV65164628, COSV65165383, COSV65165412; called by muse, varscan2
- PIM1 | c.703A>T p.M235L | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV100998576; called by muse, varscan2
- POM121L12 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs778713354, COSV101374810; called by muse, mutect2, varscan2
- PRKN | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100626843; called by muse, mutect2, varscan2
- PSG11 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.976); catalogued as COSV100105333; called by muse, mutect2, varscan2
- RASSF10 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV61754296; called by muse, mutect2, varscan2
- RBM38 | c.329A>C p.Y110S | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV100654719; called by muse, mutect2, varscan2
- RGL3 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs750883806, COSV100992804, COSV66512198; called by muse, mutect2, varscan2
- RHBDF2 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs776130866, COSV99166162; called by muse, mutect2, varscan2
- RHOBTB1 | c.1868A>C p.N623T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV100558292; called by muse, mutect2, varscan2
- ROS1 | c.6152T>G p.L2051R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100876059; called by muse, mutect2, varscan2
- RPL13 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs139252401; called by muse, mutect2, varscan2
- SCN7A | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV69274024; called by muse, mutect2, varscan2
- SENP2 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs375476062; called by muse, mutect2, varscan2
- SLA | c.371T>C p.V124A (on ENST00000338087 / NM_001045556.3; = p.V164A on NM_006748.4) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99598433; called by muse, mutect2, varscan2
- SLC28A3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100883115; called by muse, mutect2
- SLC45A2 | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV99672196; called by muse, mutect2, varscan2
- SLC7A2 | c.692G>C p.S231T (on ENST00000494857 / NM_001370338.1; = p.S271T on NM_003046.6) | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99134240; called by muse, mutect2, varscan2
- SLC9B2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs768736288, COSV60017498; called by muse, mutect2, varscan2
- SORL1 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99492541; called by muse, mutect2, varscan2
- SULT1C2 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV99264927; called by muse, mutect2, varscan2
- TADA2B | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.31); catalogued as rs1264916792, COSV99380506; called by muse, mutect2, varscan2
- TBX5 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100090233; called by muse, mutect2, varscan2
- TERB2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 103/466 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs752855886, COSV100546479; called by muse, mutect2, varscan2
- TLR3 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710737; called by muse, mutect2, varscan2
- TRIM4 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100584117; called by muse, mutect2, varscan2
- TSC22D1 | c.2984T>G p.L995W (on ENST00000458659 / NM_183422.4; = p.L66W on NM_006022.4) | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99817844; called by muse, mutect2, varscan2
- TTYH2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs773235765, COSV99482742; called by muse, mutect2, varscan2
- UAP1L1 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1421898342, COSV100814387; called by muse, mutect2, varscan2
- UBN1 | c.961A>G p.S321G | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99277279; called by muse, mutect2, varscan2
- UBR4 | c.3884C>T p.T1295I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.353); catalogued as COSV100919951; called by muse, mutect2, varscan2
- UCKL1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62402294; called by muse, mutect2, varscan2
- UGT2B17 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1309228581, COSV100497142; called by muse, mutect2, varscan2
- USP9X | c.4339T>A p.F1447I | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100198306; called by muse, mutect2, varscan2
- ZBED1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58136154; called by muse, mutect2
- ZFHX4 | c.6463A>G p.S2155G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV99254493; called by muse, mutect2, varscan2
- ZNF141 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV99549277; called by muse, mutect2, varscan2
- ZNF208 | c.809C>A p.A270E | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV101236631; called by muse, mutect2
- ZNF721 | c.2687T>C p.L896P (on ENST00000338977; = p.L908P on NM_133474.4) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100166868; called by muse, mutect2, varscan2
- ANKRD30A | c.337-13_343del p.X113_splice (on ENST00000611781; = p.X57_splice on NM_052997.2) | Splice Site (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel
- CSNK2A1 | c.684del p.K229Rfs*15 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | called by mutect2, pindel, varscan2
- ETV6 | c.26_33+2delinsCCA p.X9_splice | Splice Site (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2*
- IGHA1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHG2 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, varscan2
- IGHG2 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- IGHG2 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IGHG4 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHM | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TNFAIP3 | c.1880_1881del p.C627Ffs*44 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by pindel, varscan2
- TOX | c.921del p.K307Nfs*16 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- ABL1 | c.114G>A p.E38= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100583304, COSV59343851; called by muse, mutect2, varscan2
- ACTG1 | c.333C>T p.N111= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs727502884, COSV59509851; ClinVar: likely benign; called by muse, varscan2
- BTG2 | c.198C>G p.R66= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99305491; called by muse, mutect2, varscan2
- CACNA1F | c.1122G>A p.E374= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1297687029, COSV100544237; called by muse, mutect2, varscan2
- CCND2 | c.21G>A p.E7= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99713946; called by muse, mutect2, varscan2
- CHRM3 | c.1737C>A p.V579= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV99697197; called by muse, mutect2, varscan2
- DENND3 | c.1599C>T p.Y533= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV99370153; called by muse, mutect2
- DLC1 | c.2076G>A p.L692= (on ENST00000276297 / NM_001348081.2; = p.L255= on NM_006094.5) | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV52325854, COSV99360335; called by muse, mutect2, varscan2
- DMRT2 | c.1044C>A p.G348= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV99425878; called by muse, mutect2, varscan2
- DUOX2 | c.267G>A p.T89= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99972665; called by muse, mutect2, varscan2
- ETAA1 | c.612G>A p.E204= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs1009336895, COSV99712520; called by muse, mutect2, varscan2
- FAM171A1 | c.1110G>A p.A370= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as rs769274660, COSV65319950; called by muse, mutect2, varscan2
- FAM83G | c.294C>T p.G98= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100524694, COSV58761769; called by muse, mutect2, varscan2
- GIN1 | c.231C>T p.C77= | Silent (SNP) | VAF 32/490 reads (7%) | catalogued as rs782129439, COSV101204248; called by muse, mutect2
- GPD2 | c.891G>T p.V297= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV100132789; called by muse, mutect2, varscan2
- GSN | c.423C>T p.G141= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- HAS1 | c.300C>T p.T100= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs1193319179, COSV99708161; called by muse, mutect2, varscan2
- HECTD1 | c.1737C>A p.I579= | Silent (SNP) | VAF 73/300 reads (24%) | catalogued as COSV101237287, COSV101237625; called by muse, mutect2, varscan2
- HR | c.2784A>G p.P928= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs762093739, COSV100455601; called by muse, mutect2, varscan2
- IGHA1 | c.829C>T p.L277= | Silent (SNP) | VAF 42/416 reads (10%) | called by muse, varscan2
- IGHE | c.357G>A p.S119= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs373740475; called by muse, mutect2, varscan2
- IGHG2 | c.678G>A p.Q226= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as rs1272656535; called by muse, varscan2
- IGHG2 | c.246C>T p.T82= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- IGHM | c.213G>A p.V71= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, varscan2
- IGHV2-70 | c.120C>T p.T40= | Silent (SNP) | VAF 58/220 reads (26%) | catalogued as rs538449396; called by muse, varscan2
- INPP4B | c.1899T>G p.A633= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs751391028, COSV99522695; called by muse, mutect2, varscan2
- ITGAV | c.1617A>C p.R539= | Silent (SNP) | VAF 35/181 reads (19%) | catalogued as COSV99654062; called by muse, mutect2, varscan2
- MAST4 | c.7395C>T p.F2465= (on ENST00000403625 / NM_001164664.2; = p.F2276= on NM_015183.3) | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV55125848; called by muse, mutect2, varscan2
- MERTK | c.2253C>T p.G751= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs149178674; called by muse, mutect2, varscan2
- MPEG1 | c.1275C>T p.I425= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99914868; called by muse, mutect2, varscan2
- NEMP1 | c.156T>G p.L52= | Silent (SNP) | VAF 50/232 reads (22%) | catalogued as COSV100271954; called by muse, mutect2, varscan2
- NHLRC2 | c.709A>C p.R237= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100992864; called by muse, mutect2, varscan2
- NRF1 | c.555G>T p.L185= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99781359; called by muse, mutect2, varscan2
- NUDT8 | c.399G>A p.S133= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs768052611, COSV100039578; called by muse, mutect2, varscan2
- OR10Q1 | c.714C>A p.G238= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100372101; called by muse, mutect2, varscan2
- OSCAR | c.27G>A p.L9= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PAN2 | c.3312C>G p.V1104= (on ENST00000425394 / NM_001127460.3; = p.V1100= on NM_014871.5) | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV99228023; called by muse, mutect2, varscan2
- PIM1 | c.378G>T p.V126= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100998572; called by muse, varscan2
- PIM1 | c.531C>T p.L177= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1259173458, COSV100998573; called by muse, mutect2, varscan2
- PLEKHM2 | c.1770C>T p.N590= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV101008998; called by muse, mutect2, varscan2
- PLK2 | c.69C>T p.G23= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV99955691; called by muse, mutect2, varscan2
- PLPPR5 | c.228C>T p.P76= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs148163708, COSV99586840; called by muse, mutect2, varscan2
- PLXNA1 | c.4737C>T p.N1579= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs369457038; called by muse, mutect2, varscan2
- RBFOX1 | c.1056C>T p.Y352= | Silent (SNP) | VAF 90/182 reads (49%) | catalogued as rs372365163; called by muse, mutect2, varscan2
- SBNO2 | c.4008C>T p.G1336= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1317301774, COSV100683915; called by muse, mutect2, varscan2
- SLC8A1 | c.1587A>G p.V529= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV100243972; called by muse, mutect2, varscan2
- SRRM1 | c.2346A>T p.P782= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as COSV100103927; called by muse, mutect2, varscan2
- SV2B | c.1975C>T p.L659= | Silent (SNP) | VAF 51/206 reads (25%) | catalogued as COSV100370305; called by muse, mutect2, varscan2
- UPK3B | c.648A>G p.R216= (on ENST00000257632; = p.D188G on NM_001347684.2) | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV99990940; called by muse, mutect2, varscan2
- VANGL2 | c.945C>T p.S315= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1011438478, COSV100925506; called by muse, mutect2, varscan2
- WAS | c.1039T>C p.L347= | Silent (SNP) | VAF 90/174 reads (52%) | catalogued as rs782337048, COSV100939418; called by muse, mutect2, varscan2
- ZNF875 | c.1224A>T p.S408= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100182983; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417446 C>T | 3'Flank (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- MIR124-1 | n.5C>T | RNA (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- MIR1261 | n.46G>C | RNA (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- MIRLET7A1 | n.10G>A | RNA (SNP) | VAF 32/156 reads (21%) | called by muse, mutect2, varscan2
- SSPOP | n.2424G>A | RNA (SNP) | VAF 4/27 reads (15%) | catalogued as rs746584710, COSV100022015; called by muse, mutect2, varscan2
